Surgical pathology report (de-identified scan), TCGA case TCGA-S4-A8RM, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site University of Chicago, specimen TCGA-S4-A8RM-01A (Primary Tumor).

[page 1 of 5]
Gender: Male

Race: White

Pathology Report:

ICD-O-3
Adenocarcinoma, duct NOS 8500/3
Site ^{C&F} Pancreas NOS C25.9
^{path} Pancreas tail C25.2
JW 3/12/14

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

Pancreaticoduodenectomy and splenectomy;

A. Liver segment:

- Hyalinized granuloma, no tumor.

B. Duodenal mass:

- Benign mesothelial cyst.

C. Gallbladder:

- Gallbladder without diagnostic abnormality.

D. Bile duct stent:

- Surgical hardware, consistent with stent.

E. Pancreatectomy:

- Invasive ductal adenocarcinoma (foamy gland type), arising from a brand-duct intraductal papillary mucinous neoplasm (BD-IPMN). See pathologic parameters.

- One of nine lymph nodes positive for metastatic carcinoma (1/9).

F. Splenectomy:

- Spleen without diagnostic abnormality.

G. Gastric staple line:

- Portion of stomach, no tumor.

H. Omentum:

- Vascularized fibroadipose tissue, no tumor.

PANCREAS (EXOCRINE): Resection

Tumor Size

Greatest dimension: 6 cm

*Additional dimensions: 3 x 2.7 cm

Histologic Type (select all that apply)

Ductal adenocarcinoma

Intraductal papillary-mucinous carcinoma (BD-IPMN)

Invasive

[page 2 of 5]
Histologic Grade (ductal carcinoma only)

G3: Poorly differentiated

Margins (select all that apply)

Margins uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest margin: 1 mm

*Specify margin (if possible): Uncinate

Treatment Effect (applicable to carcinomas treated with neoadjuvant therapy)

(select all that apply)

No prior treatment

Lymph-Vascular Invasion

Present

Perineural Invasion

Present

Pathologic Staging (pTNM): pT3, N1, MX

Primary Tumor (pT)

pT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery

Regional Lymph Nodes (pN)

pN1: Regional lymph node metastasis

Specify: Number examined: 9

Number involved: 1

Distant Metastasis (pM)

Not applicable

*Effective January 1, 2010 this Checklist utilizes the 7th edition TNM staging system for pancreas exocrine of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

Comment

The tumor invades into the duodenal wall, the serosal side of the adhered gastric wall. A cystic lesion (slide E15) exhibits features of a branch duct-intraductal papillary mucinous neoplasm. Therefore, the invasive carcinoma is interpreted as arising from the IPMN.

xxx

[page 3 of 5]
[], M.D.

Interpretation performed by the Attending Pathologist and reviewed with the Resident/Fellow, [], MD

Electronically Signed Out by [] M.D.

Clinical History:

The patient is a -year-old male with pancreatic cancer who undergoes Whipple procedure.

Specimens Received:

- A: Liver segment
- B: Duodenal mass
- C: Gallbladder
- D: Bile duct stent
- E: Pancreatectomy
- F: Splenectomy
- G: Gastric staple line
- H: Omentum

Gross Description:

The specimens are received in eight containers each labeled with the patient's name and medical record number.

A. The first container is additionally identified as, "1. Liver segment".

Received fresh for intraoperative diagnosis is a red black irregular soft tissue fragment measuring 0.9 x 0.7 x 0.1 cm which is entirely frozen. The diagnosis is "scar, no tumor" as read by Dr. []. The entire specimen is submitted in A1 FS.

B. The second container is additionally identified as, "2. Duodenal mass".

Received fresh for intraoperative diagnosis is a tan-yellow soft tissue fragment measuring 0.4 x 0.2 x 0.1 cm which is entirely frozen. The diagnosis is "cyst, benign" as read by Dr. []. The entire specimen is submitted as B1 FS.

C. The third container is additionally identified as, "3. Gallbladder".

Received fresh in a laparoscopic bag is a 7.5 x 3.8 x 2.8 cm gallbladder. The serosa is tan-pink, glistening and cauterized along the hepatic attachment. The specimen is opened adjacent to the bile duct revealing green-tan, velvety mucosa with diffuse gold speckling. The mucosal wall thickness is 0.2 cm. The opened specimen reveals multiple yellow, friable stones measuring from 0.3-0.5 cm in greatest dimension. Grossly, the stones do not obstruct the bile duct. There is 3 ml of viscous brown bile. Representative sections of the fundus, body, and bile duct margin are submitted in cassette C1.

D. The fourth container is additionally identified as, "4. Bile duct stent".

Received is a 6.5 cm in length by 0.8 cm in diameter gray wire metal stent which

[page 4 of 5]
is intact. A photograph is taken. This is a gross description only.

E. The fifth container is additionally identified as, "5.

Pancreaticoduodenectomy including total pancreatectomy". Received fresh and placed in formalin is a Whipple specimen that consists of a 14 cm in length segment of duodenum with an internal circumference of 7 cm, 7.5 x 5.5 x 1.5 cm segment of distal stomach, and 13 x 4.5 by 4 cm portion of pancreas. The uncinate margin is inked black, the portal vein groove margin is inked blue, and the posterior margin is inked red. The margins are trimmed, serially sectioned and submitted. The common bile duct is dilated at the resection margin with a diameter of 0.7 cm. Serial sectioning of the pancreas reveals a 6 x 3 x 2.7 cm firm, white, well-circumscribed mass with focally cystic areas and is located in the tail of the pancreas. The mass is almost entirely replaces the pancreas. The mass is less than 0.1 cm from the uncinate margin, less than 0.1 cm to the portal vein groove margin, and 0.3 cm from the posterior margin. The mass entirely obliterates the pancreatic duct and encases the common bile duct, extending to involve the ampulla of Vater. The mass does not grossly invade the duodenum and stomach wall. The remaining pancreatic parenchyma is yellow-tan, rubbery and lobulated. In the pancreatic tail, the mass encases the splenic vein and artery. The stomach and duodenum reveal grossly unremarkable, tan mucosa with a uniform 0.4 cm wall thickness. The peripancreatic adipose tissue is extensively dissected to reveal one pink-gray fibrofatty lymph node measuring up to 2.3 cm in greatest dimension.

Block summary:

E1: Bile duct margin

E2: Portal vein groove margin

E3-E4: Uncinate margin

E5-E7: Posterior margin

E8: Stomach margin

E9: Duodenal margin

E10: Mass in relation to ampulla of Vater

E11: Mass in relation to common bile duct

E12: Mass in relation to stomach

E13: Mass in relation to duodenum

E14: Mass, pancreatic tail, encasing splenic artery and vein

E15-17: Mass, pancreatic tail, cystic areas

E18: Mass in relation to stomach and uninvolved pancreas

E19-21: Additional sections of mass

E22: One lymph node, bisected

E23-E30: Peripancreatic adipose tissue.

F. The sixth container is additionally identified as, "6. Splenectomy".

Received fresh is a 408.8 gm spleen measuring 14.5 x 9.5 x 5.5 cm with attached yellow lobulated adipose tissue measuring 12.5 x 12 x 3 cm. The outer capsule is smooth, purple-gray and glistening. The spleen is serially sectioned to reveal

[page 5 of 5]
soft, red-brown, homogenous cut surface with no masses or lesions. The fibroadipose tissue is extensively dissected for lymph nodes; none are found. No nodules or lesions are present in the fibroadipose tissue. Representative sections are submitted as follows:

F1-F2: Spleen

F3-F4: Fibroadipose tissue

G. The seventh container is additionally identified as, "7. Gastric staple line". Received fresh and placed in formalin is a fragment of tan soft tissue measuring 5.5 x 0.8 x 0.8 cm. A staple line is present measuring 5 cm. The staple line is removed and the remaining soft tissue is submitted in cassette G1-G2.

H. The eighth container is additionally identified as, "8. Omentum". Received fresh in place in formalin are multiple fragments of yellow, lobulated fibroadipose tissue weighing 546.7 g. The specimen is extensively dissected; no nodules, lesions, or lymph nodes are identified. A representative section of the specimen is submitted in cassette H1.

xxx

[], M.D.

Source: NCI Genomic Data Commons file 0526d26f-850f-45a2-9ab5-dd447c05366f (TCGA-S4-A8RM.4D1E4F48-60FC-4982-AF71-81859F14ABB4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).